Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VL, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VL-01A (Primary Tumor).

[page 1 of 4]
Head & Neck
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right thyroid nodule with follicular cells.

Specimens Submitted:

- 1: Delphian node (fs)
- 2: Total thyroidectomy

DIAGNOSIS:

1. Delphian node; excision:
- Benign glandular and lymphoid tissue consistent with lymphocytic thyroiditis

2. Total thyroidectomy:

Tumor Type:

Papillary microcarcinoma

pap TSS - 99% follicular variant.

Histologic Grade:

Well differentiated

See attached TCGA Pathologic Dx Discrepancy Form for

Mitotic Activity:

Not identified

ICD-O-3

Tumor Necrosis:

Not identified

Carcinoma, papillary, follicular variant

Tumor Location:

Right lobe

Site: thyroid, NOS

8340/3

Tumor Size:

Greatest diameter is 0.6 cm.

*C73.9 5-2-12
RD*

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

[page 2 of 4]
Lymph Nodes:

One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for intraoperative consultation and is labeled "Delphian node". It consists of one piece of tan pink soft tissue, measuring 0.8 x 0.6 x 0.2 cm. Specimen is entirely submitted for frozen section.

Summary of sections:

FSC-frozen section control

2). The specimen is received fresh, labeled "total thyroidectomy stitch marks right lobe of thyroid" and consists of a thyroid weighing 12.5 g. The right lobe measures 3.8 x 2.4 x 1.4 cm, the left lobe measures 3.4 x 2 x 1 cm and the isthmus measures 1.9 x 1.3 x 0.7 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals two nodules in the right lobe: N1- 0.3 cm white, hard, poorly circumscribed, in the upper pole, and N2 - 0.6 x 0.5 x 0.5 cm light brown, encapsulated, in the mid pole. Sections through the remaining tissue reveal no other lesions. The remaining thyroid parenchyma is red tan and beefy. Representative sections of N2 are submitted for . The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N1 - nodule 1

N2 - nodule 2

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Delphian node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	3
4	LL	4
1	N1	1
1	N2	1
4	RL	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Delphian node (fs): Lymphoid tissue and benign glandular tissue

[page 3 of 4]
Permanent diagnosis: Same

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Papillary microcarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Follicular variant of papillary carcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Subcentimeter papillary carcinomas are labeled as microcarcinomas. They can be follicular variant, clumped or others. Both diagnoses do not contradict each other.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

is the pathologist and the PI.

Source: NCI Genomic Data Commons file 5036cb23-854f-48a8-9b71-7e9cadea78ec (TCGA-DJ-A3VL.B84A9460-C19C-4AAC-8C08-1631C2DA08DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).